National Lung Screening Trial (NLST) participant 214672 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 58 years; Gender: female; Race: Black or African-American; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 75 mA, display field of view 28 cm, reconstruction filter Siemens B50F / Siemens B30.
- T1 (day 355): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 50 mA, display field of view 28 cm, reconstruction filter Siemens B50F / Siemens B30.
- T2 (day 1,147): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 50 mA, display field of view 28 cm, reconstruction filter Siemens B50F / Siemens B30.

Abnormalities recorded by the reading radiologist on the CT screens (8 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 8 mm, longest perpendicular diameter 5 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 45.
- T0 abnormality 2: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 9 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation ground glass; greatest diameter on CT slice 99.
- T1 abnormality 2: Significant cardiovascular abnormality.
- T1 abnormality 3: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 12 mm, longest perpendicular diameter 12 mm; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 36; pre-existing on earlier images (earliest visible day 0); interval growth; suspicious interval change in attenuation.
- T2 abnormality 2: Other potentially significant abnormality above the diaphragm.
- T2 abnormality 3: Other potentially significant abnormality above the diaphragm.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T2; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,220, study year T2. Site: lower lobe of lung (ICD-O-3 C34.3), determined from histology. Primary tumour location: right upper lobe. Histology: bronchiolo-alveolar adenocarcinoma, NOS (ICD-O-3 8250/3). Grade: moderately differentiated (G2). Tumour size on pathology: 17 mm. AJCC 6th edition staging: stage IIIB (best stage, from pathologic TNM); clinical T4 N0 M0 (stage IIIB); pathologic T4 N0 M0 (stage IIIB). AJCC 7th edition staging: stage IIB; clinical T3 N0 M0; pathologic T3 N0 M0. Summary stage: regional.

Follow-up
Last known free of lung cancer: day 1,220 (for ACRIN participants with lung cancer this field holds the diagnosis date).
